Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA53, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA53-01A (Primary Tumor).

Specimen Comments

SPECIMEN

1 - Bladder and prostate

CLINICAL DETAILS

Bladder cancer.

MACROSCOPY

Specimen comprises bladder and prostate measuring in total 160 mm supero-inferiorly, 95 mm transverse, and 60 mm anterior-posterior. Total weight = 460g. The bladder contains an extensively necrotic polypoid tumour on the posterior wall measuring at least 40 x 70 x 30 mm. The tumour is close to the detrusor muscle and is 8 mm from the posterior serosal margin. There are bilateral ureteric stumps measuring 5 x 4 mm each.

MICROSCOPY

There is a poorly differentiated, Grade 3, transitional carcinoma involving the lateral and posterior wall, close to and surrounding the right ureter. It invades muscularis propria. It extends to within 9 mm of the prostate, but there is no convincing evidence of invasion into the perivesical fat. Squamous differentiation is noted, but elsewhere the tumour has a spindle cell/sarcomatoid appearance. It does not show the lymphoepithelioma-like appearance suggested on the previous biopsy.

No vascular invasion has been identified. The circumferential margin is clear of tumour. Both ureteric resection margins are clear of tumour. The uninvolved bladder wall is severely inflamed and focally denuded of urothelium. Where present, it shows some atypia but there is no evidence of carcinoma-in-situ. Although the urethral resection margin is clear of transitional bladder carcinoma, there is a focus of prostatic adenocarcinoma at this margin (Block 1A). There are further multiple foci of Gleason score 3 + 3 = 6 prostatic adenocarcinoma in both right and left prostatic lobes, measuring at least 14 mm in dimension. High grade prostatic intraepithelial neoplasia, PIN, is also present. There is no evidence of extracapsular extension.

SUMMARY

1 - Transitional cell carcinoma of bladder G3 pT2, completely excised.

2 - Adenocarcinoma of prostate, Gleason score 3 + 3 = 6, pT2, at urethral resection margin.

Ref:

Pathologists -

ICD O-3
carcinoma urothelial NOS 8120/3
carcinoma, transitional cell NOS 8120/3
Site: Bladder wall NOS C67.9
JP 4/30/14

Date of last BCG

Source: NCI Genomic Data Commons file 2b489993-eaac-4b4c-bb89-2fc07aa15048 (TCGA-ZF-AA53.07A1F163-55AF-4D64-AFD9-DE8DFF7CB2C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).